CCDI case PBCAMX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b857eb1b-24a4-49ff-aa0b-4803c1a2f464

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 10.2 years (3,735 days).

Biospecimens (3 samples)
- Sample 0DMRAP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMRAX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMRB7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
